Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6161, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6161-01A (Primary Tumor).

[page 1 of 4]
....

Clinical Diagnosis & History:
[REDACTED] with history of rectal cancer.

Specimens Submitted:
1: COLON, SIGMOID; RESECTION:
2: SP: Proximal ring
3: SP: Distal ring

DIAGNOSIS:
1. COLON, SIGMOID; RESECTION::
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Sigmoid colon
Tumor Size:
Length is 6.5 cm
Width is 4.5 cm
Maximal thickness is 2.5 cm
Tumor Budding:
Absent
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Tubulovillous adenoma
Deepest Tumor Invasion:
Muscularis propria
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Not identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Not identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Tubular adenoma; number: 1

** Continued on next page **

[page 2 of 4]
[REDACTED]

Non-Neoplastic Bowel:
Unremarkable
Lymph Nodes:
Number with metastasis: 0
Total number examined: 31
Tumor deposits in pericorectal soft tissue:
Not Identified
Tumor Staging (AJCC 7th Edition):
pT2 (Tumor invades muscularis propria)
Lymph Node Stage (AJCC 7th Edition):
N0 (No regional lymph node metastasis)

NOTE:
RESULTS OF IMMUNOHISTOCHEMICAL STAINING FOR DNA MISMATCH REPAIR PROTEINS ARE
AS FOLLOWS:

MLH1: STAINING PRESENT IN TUMOR
MSH2: STAINING PRESENT IN TUMOR
MSH6: STAINING PRESENT IN TUMOR
PMS2: STAINING PRESENT IN TUMOR
CONCLUSION: IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR
PROTEINS IS RETAINED IN THE TUMOR.

2. COLON, PROXIMAL RING; EXCISION:
- BENIGN COLONIC TISSUE.
- A DETACHED FRAGMENT OF ADENOMATOUS MUCOSA IS NOTED.
3. COLON, DISTAL RING; EXCISION:
- BENIGN COLONIC TISSUE.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

[REDACTED]

1. The specimen is received fresh and is labeled "Sigmoid". It consists of an undesignated sigmoid colon (19.5 cm in length and ranges in circumference from 6.2 to 8.0 cm) with attached pericolic fat (17.3 x 8.5 x 2.5 cm). The

** Continued on next page **

[page 3 of 4]
serosal surface is pink, glistening and intact. The presumed distal resection margin is inked black and presumed proximal resection margin is inked red. The specimen is opened to reveal an exophytic, bosselated, tumor (6.5 cm in length and 4.5 cm in width) that is located 10.0 cm from the proximal margin and 4.5 cm from the distal margin. Serial sectioning reveals the tumor has a depth of 2.5 cm. Thorough sectioning show that the tumor appears to be limited to the muscularis propria without invasion beyond the muscle. There is 2nd tan polypoid mass , located 1.5 cm from the tumor which is sampled. The remaining mucosa is grossly unremarkable. Pericolonic and perirectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. The tumor area is extensively sampled. TPS is submitted.

Summary of sections:

PM - proximal margin, shave

DM - distal margin, shave

T tumor

P- polypoid mass

U - uninvolved mucosa

LN - lymph nodes

BLN - bisected lymph node

TU more sections from the tumor

2. The specimen is received in formalin, labeled "Proximal ring" and consists of a silver metal anastomotic pin measuring 7.5 x 2.8 x 1.5 cm. At the center of the pin, a blue plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2.3 x 2.2 x 1.1 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U--undesignated

3. The specimen is received in formalin, labeled "Distal ring" and consists of a ring of pink tan soft tissue measuring 2.2 x 1.9 x 0.8 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U--undesignated

Summary of Sections:

Part 1: COLON, SIGMOID; RESECTION:

** Continued on next page **

[page 4 of 4]
Block	Sect.	Site	PCs
1		BLN	2
1		DM	2
7		Ln	21
1		P	1
1		PM	2
11		TU	14
1		U	1

Part 2: SP: Proximal ring

Block	Sect.	Site	PCs
1		U	8

Part 3: SP: DIstal ring

Block	Sect.	Site	PCs
1		U	5

** End of Report **

Source: NCI Genomic Data Commons file 6e263825-3c0c-4c12-b572-977fdafdb6ce (TCGA-CM-6161.9073483F-FB96-4CF2-B257-8A24C8E1BB07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).